Gene-level copy-number profile of tumor specimen TCGA-BT-A20J-01A from TCGA case TCGA-BT-A20J, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Posterior wall of bladder; AJCC pathologic stage: Stage II; Tumor grade: High Grade; Age at diagnosis: 75.7 years (27,646 days).
Specimen TCGA-BT-A20J-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.4e8d3f4a-8cf5-4444-9dc9-6b726f899f10.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-BT-A20J-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 813 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/9da197cd-0be2-4d5f-bdc3-4d3edfdaba42

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 79; copy number 1: 810; copy number 2: 21,391; copy number 3: 21,595; copy number 4: 10,512; copy number 5: 3,401; copy number 6: 397; copy number 7: 194; copy number 8: 578; copy number 9: 260; copy number 10: 60; copy number 11: 179; copy number 13: 57; copy number 16: 29; copy number 17: 12; copy number 20: 2; copy number 23: 80; copy number 26: 13; copy number 29: 7; copy number 32: 93; copy number 35: 47; copy number 36: 6; copy number 45: 1; copy number 48: 7.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-BT-A20J-01A-11D-A14V-01): tumor purity 0.4, ploidy 3.07, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 75 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:20,658,309–22,824,213, 61 genes (within-gene range 0–2) (broad region; genes not listed).
- chr9:22,747,700–22,768,316, 2 genes: CLIC4P1, AC017067.1.
- chr9:26,642,697–27,104,728, 12 genes: AL442639.1, AL451137.2, AL451137.1, AL356133.1, CAAP1, H3P31, RN7SL100P, PLAA, IFT74, IFT74-AS1, LRRC19, AL355432.1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,625 genes in 21 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:39,081,316–43,285,617, 137 genes, copy number 32–35 (within-gene range 2–35) (broad region; genes not listed).
- chr1:74,963,314–96,696,167, 356 genes, copy number 8–36 (broad region; genes not listed).
- chr1:150,363,091–151,993,859, 96 genes, copy number 8 (within-gene range 4–8) (broad region; genes not listed).
- chr2:211,535,653–211,779,763, 3 genes, copy number 7: RNA5SP119, MTND2P23, MTCO1P46.
- chr6:80,003,887–83,709,691, 38 genes, copy number 7 (within-gene range 4–7): TTK, AL591135.2, AL591135.1, AK4P5, BCKDHB, AL359715.3, RPL17P25, AL359715.4, AL359715.1, AL359715.2, RPSAP72, AL596028.1, AL590824.1, TENT5A, AL122017.1, AL359693.1, RNA5SP210, AL078599.2, SNORA70, AL078599.1, LINC01526, LINC02542, AL360157.1, IBTK, RNU6-130P, AL121977.1, AL121977.2, TPBG, UBE3D, LAP3P1, AL355613.1, DOP1A, PGM3, RWDD2A, ME1, AL391416.1, PRSS35, SNAP91.
- chr6:103,002,514–107,459,564, 53 genes, copy number 13–48 (within-gene range 2–48): Z98755.1, AL591387.1, AL590608.1, R3HDM2P2, NPM1P10, AL357522.1, AL356967.1, HACE1, RNU6-897P, AL357315.1, AL357315.2, LIN28B-AS1, LIN28B, RNU6-1106P, BVES, BVES-AS1, POPDC3, PREP, AL133406.2, AL133406.1, RPL35P3, AL096794.1, LINC02836, Z97206.1, AL591518.1, RN7SKP211, PRDM1, ATG5, AL022067.1, U4, RN7SL47P, RNU6-344P, AL356859.1, CRYBG1, Y_RNA, RNA5SP211, AL109920.1, Y_RNA, RTN4IP1, RNU6-527P, QRSL1, RPL21P65, LINC02526, LINC02532, RNU6-117P, MIR587, CD24, MTRES1, BEND3, RNU6-1299P, PDSS2, AL591516.1, RPS24P12.
- chr7:31,330,711–36,841,373, 94 genes, copy number 9–13 (broad region; genes not listed).
- chr7:36,919,357–37,013,630, 2 genes, copy number 10: MIR1200, ELMO1-AS1.
- chr7:50,304,068–64,266,931, 280 genes, copy number 7–13 (within-gene range 5–13) (broad region; genes not listed).
- chr7:77,122,434–77,329,533, 1 gene, copy number 10 (within-gene range 4–10): CCDC146.
- chr7:77,246,340–77,957,503, 11 genes, copy number 10 (within-gene range 3–10): AC098851.1, GSAP, AC004921.1, GCNT1P5, AC004921.2, PTPN12, APTR, RSBN1L, TMEM60, PHTF2, Y_RNA.
- chr7:90,466,424–91,210,590, 1 gene, copy number 9 (within-gene range 3–9): CDK14.
- chr7:91,030,149–94,011,113, 54 genes, copy number 9 (within-gene range 3–9): AC002458.1, PTP4A1P3, FZD1, AC079760.2, NIPA2P1, AC079760.1, AC000058.1, MTERF1, AC003086.1, AKAP9, CYP51A1, AC000120.2, AC000120.3, CYP51A1-AS1, LRRD1, KRIT1, AC000120.1, Y_RNA, MIR1285-1, ANKIB1, TMBIM7P, AC007566.2, GATAD1, AC007566.1, ERVW-1, PEX1, RBM48, AC005156.1, FAM133B, CDK6, AC000065.2, AC000065.1, RNU6-10P, CDK6-AS1, RN7SL7P, SAMD9, SAMD9L, HEPACAM2, VPS50, CALCR, MIR653, MIR489, GNGT1, AC002075.2, MIR4652, AC002075.1, NDUFAF4P2, TFPI2, TFPI2-DT, AC002076.1, GNG11, AC006378.1, BET1, BET1-AS1.
- chr8:37,067,441–37,069,418, 1 gene, copy number 11: AC092818.1.
- chr8:78,516,340–84,164,564, 92 genes, copy number 9 (broad region; genes not listed).
- chr12:564,296–10,066,031, 357 genes, copy number 8–23 (broad region; genes not listed).
- chr13:73,036,401–73,661,891, 10 genes, copy number 7: PSMD10P3, KLF5, FABP5P1, RNU6-66P, RNU4-10P, RNY1P8, AL162376.1, MARK2P12, LINC00393, LINC00392.
- chr13:73,800,074–73,802,203, 1 gene, copy number 7: AL138713.1.
- chr13:74,828,553–76,135,225, 19 genes, copy number 7: RIOK3P1, RNU6-38P, SSR1P2, CTAGE11P, LINC01078, TBC1D4, AL139230.1, COMMD6, UCHL3, AL137782.1, LMO7-AS1, LMO7, AL137244.1, FAM204CP, LMO7DN, LMO7DN-IT1, LINC00561, LINC01034, RN7SL571P.
- chr15:25,738,508–25,738,620, 1 gene, copy number 7: RNA5SP390.
- chr18:25,818,234–26,657,401, 18 genes, copy number 7 (within-gene range 2–7): RN7SL97P, AC027229.1, SS18, RPS24P18, PSMA8, DHFRP1, NPM1P2, TAF4B, SINHCAFP1, AC121320.1, AC022069.1, RNU6-1289P, LINC01543, KCTD1, AC007996.1, AC090206.1, MIR8057, CIAPIN1P.

Autosomal genes at a single copy (total copy number 1): 778. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
